Gene-level copy-number profile of tumor specimen TCGA-DS-A0VK-01A from TCGA case TCGA-DS-A0VK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G3; Age at diagnosis: 46.0 years (16,792 days).
Specimen TCGA-DS-A0VK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.a434839c-d61f-4864-ad76-ae82588e21e1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DS-A0VK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d86f5c30-21a9-434f-abdd-48154cd30cfb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 11,884; copy number 2: 44,042; copy number 3: 2,126; copy number 4: 1,000; copy number 5: 636; copy number 7: 21; copy number 8: 6; copy number 10: 64; copy number 20: 9; copy number 21: 1; copy number 52: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DS-A0VK-01A-21D-A10T-01): tumor purity 0.67, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:132,410,636–132,488,702, 1 gene (within-gene range 0–1): IRF1-AS1.
- chr5:132,468,147–132,490,777, 3 genes: Y_RNA, AC116366.1, IRF1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 757 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:170,037,995–198,222,513, 564 genes, copy number 5 (broad region; genes not listed).
- chr7:54,933,699–55,260,256, 6 genes, copy number 8: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr17:57,861,243–59,537,499, 72 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:74,670,077–76,083,666, 84 genes, copy number 7–10 (broad region; genes not listed).
- chr17:76,090,308–76,091,669, 1 gene, copy number 10: AC018665.1.
- chr20:31,257,664–31,723,989, 30 genes, copy number 20–52: DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON.

Autosomal genes at a single copy (total copy number 1): 10,423. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
